Gene-level copy-number profile of tumor specimen TCGA-2G-AAET-01A from TCGA case TCGA-2G-AAET, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Seminoma, NOS; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 41.1 years (14,997 days).
Specimen TCGA-2G-AAET-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file fe03b774-bd62-46a1-8754-ec6d2ac420a5.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator TCGA-2G-AAET-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,706 have no estimate.
https://portal.gdc.cancer.gov/files/4cc8611c-a39a-4b34-bd04-f9fc6cbe1564

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 3; copy number 1: 512; copy number 2: 4,368; copy number 3: 19,350; copy number 4: 26,044; copy number 5: 5,616; copy number 6: 2,866; copy number 7: 154; copy number 8: 4.

Homozygous deletions (total copy number 0; autosomes only): 3 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:75,521,803–75,522,012, 1 gene: SNRPCP10.
- chr3:75,542,149–75,542,929, 1 gene (within-gene range 0–4): RPS3AP15.
- chr3:130,048,143–130,055,920, 1 gene: AC083906.4.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
